Somatic mutation profile of tumor specimen TARGET-10-PARSJH-09A (aliquot TARGET-10-PARSJH-09A-01D) from TARGET case TARGET-10-PARSJH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.7 years (6,089 days).
Specimen TARGET-10-PARSJH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2addd257-6210-41ba-af0b-a14f363c3fe1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARSJH-14A (Bone Marrow Normal), aliquot TARGET-10-PARSJH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da4e0ba2-407a-47c6-b43c-29855c2a2110

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 3'UTR 2, Frame Shift Del 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MPZ | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as CM1511287; called by muse, mutect2, varscan2
- PLK5 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs780060881; called by muse, varscan2
- SNCG | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs781623510; called by muse, mutect2, varscan2
- SCCPDH | c.1135del p.V379Ffs*5 | Frame Shift Del (DEL) | VAF 32/64 reads (50%) | called by mutect2, varscan2
- UBA1 | c.824T>C p.F275S | Missense Mutation (SNP) | VAF 22/22 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBA7 | c.1682A>G p.E561G | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- AC134878.2 | n.795C>T | RNA (SNP) | VAF 9/9 reads (100%) | called by muse, mutect2, varscan2
- BRF1 | c.471+318dup | Intron (INS) | VAF 27/56 reads (48%) | called by mutect2, pindel, varscan2
- IL2RA | c.*87A>G | 3'UTR (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- MYCBP2 | c.*10A>T | 3'UTR (SNP) | VAF 20/54 reads (37%) | catalogued as rs1194037691; called by muse, mutect2, varscan2
